Surgical pathology report (de-identified scan), TCGA case TCGA-FR-A44A, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of North Carolina, specimen TCGA-FR-A44A-06A (Metastatic).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Lymph nodes, left axilla, level 1, excision
- No tumor seen in 14 lymph nodes (0/14)

B: Lymph nodes, left axilla, level 1-2, excision
- Metastatic malignant melanoma in 1 of 24 lymph nodes, size of metastasis 8.8 cm in greatest dimension, with extracapsular extension of tumor identified

C: Lymph nodes, left axilla, level 3, excision
- No tumor seen in 12 lymph nodes (0/12)

Clinical History:

No clinical history is provided.

ICD-O-3
melanoma, NOS
8720/3 8/23/12
Site: lymph node, axilla
C77.3

Gross Description:

Received are three appropriately labeled containers.

Container A is additionally labeled "level 1 left axilla lymph nodes". The specimen consists of a 7.5 x 7.3 x 1.2 cm aggregate of fatty soft tissue fragments. A few and medium sized lymph node candidates are palpated. Lymph node candidates are submitted as A1-A10.

Container B is additionally labeled "level 1, level 2, left axillary dissection dissection, long = superolateral, and short = superomedial". The specimen consists of a 15 x 10.5 x 3.8 cm fatty soft tissue fragment. There is a long suture indicating superolateral and a short suture indicating superomedial. Within the specimen is an 8.8 x 6.9 x 4.2 cm firm matted tan/white mass present predominantly in the superomedial quadrant. Multiple small and medium sized lymph node candidates are palpated and submitted as per the block summary. Upper medial mass: On cut section, the mass is firm tan/white with focal yellow areas.

Block Summary:

B1-B5 - Inferomedial lymph node candidates
B6-B8 - Lower outer quadrant
B9-B15 - Upper outer segment lymph node candidates
B16 - Inner quadrant lymph node candidate

Risk: Malignancy History		X

mw
8/14/12

[page 2 of 2]
B17-B19 - Serial sections of the large upper medial mass

Container C is additionally labeled "level 3 left axillary nodes". The specimen consists of a 5.8 x 3.2 x 1.8 cm aggregate of multiple fatty soft tissue fragments. A few small and medium sized lymph node candidates are palpated. The entire specimen is submitted as C1-C9.

Source: NCI Genomic Data Commons file 6bf1909e-2f3c-4840-8f99-d57fca1f1f3a (TCGA-FR-A44A.8633CB6A-51C3-456D-9725-174016440BF1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).